Gene-level copy-number profile of tumor specimen TCGA-EJ-A65E-01A from TCGA case TCGA-EJ-A65E, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.2 years (24,558 days).
Specimen TCGA-EJ-A65E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.784e11f7-e861-4df6-9257-feea3450b8f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-A65E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e4218d48-8625-4f88-9796-16a130bc964a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 4,279; copy number 2: 55,429; copy number 3: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-A65E-01A-11D-A323-01): tumor purity 0.62, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:81,491,439–83,736,525, 26 genes: TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1, IBTK, RNU6-130P, AL121977.1, AL121977.2, TPBG, UBE3D, LAP3P1, AL355613.1, DOP1A, PGM3, RWDD2A, ME1, AL391416.1, PRSS35, SNAP91, AL136972.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,892. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
